Somatic mutation profile of tumor specimen TCGA-78-7149-01A (aliquot TCGA-78-7149-01A-11D-2036-08) from TCGA case TCGA-78-7149, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 72.0 years (26,285 days).
Specimen TCGA-78-7149-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32df12e5-0d0e-408e-9ee3-58cbf99e66be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-78-7149-10A (Blood Derived Normal), aliquot TCGA-78-7149-10A-01D-2036-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/178d9508-7d4d-4e62-b88a-83029c289c15

The open-access MAF lists 153 somatic variants for this specimen: 113 protein-altering or splice-affecting, 35 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 35, Nonsense Mutation 12, Intron 4, Frame Shift Ins 2, Frame Shift Del 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACP4 | c.1130C>G p.S377C | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV54516738, COSV54516942; called by muse, mutect2
- ADAMTS18 | c.263G>T p.R88L | Missense Mutation (SNP) | VAF 122/305 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1206732643, COSV51404362, COSV51405391; called by muse, mutect2, varscan2
- AGBL1 | c.1339C>T p.L447F | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.02); catalogued as COSV66855705; called by muse, mutect2, varscan2
- AHNAK | c.15004G>T p.E5002* | Nonsense Mutation (SNP) | VAF 27/131 reads (21%) | catalogued as COSV57211366, COSV57213384; called by muse, mutect2, varscan2
- AHNAK2 | c.9981C>G p.I3327M | Missense Mutation (SNP) | VAF 48/344 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.26); catalogued as COSV60913670; called by muse, varscan2
- AHNAK2 | c.6316G>T p.E2106* | Nonsense Mutation (SNP) | VAF 123/173 reads (71%) | catalogued as COSV60913679; called by muse, mutect2, varscan2
- ALDH18A1 | c.898A>T p.K300* | Nonsense Mutation (SNP) | VAF 52/146 reads (36%) | catalogued as COSV64662463; called by muse, mutect2, varscan2
- ALPK1 | c.1531C>T p.H511Y | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51584271; called by muse, mutect2, varscan2
- ANK1 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1445952603, COSV55874935; called by muse, mutect2, varscan2
- APBA2 | c.760C>A p.P254T | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as COSV68790512; called by muse, mutect2, varscan2
- ATP13A3 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as COSV55463706; called by muse, mutect2, varscan2
- ATP2A2 | c.1472G>A p.R491K | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58043474; called by muse, mutect2, varscan2
- BMPER | c.1764G>T p.M588I | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV51816447; called by muse, mutect2, varscan2
- CATSPER1 | c.1310G>A p.R437Q | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.061); catalogued as rs768421949, COSV56410247; called by muse, mutect2, varscan2
- CCER1 | c.996G>C p.E332D | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.17); catalogued as COSV62646592; called by muse, mutect2, varscan2
- CCL24 | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 35/84 reads (42%) | catalogued as COSV56116179; called by muse, mutect2, varscan2
- CCN4 | c.592C>A p.R198S | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.145); catalogued as COSV51530894, COSV99137203; called by muse, mutect2, varscan2
- CDH8 | c.1225G>T p.V409L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.107); catalogued as COSV100181522; called by muse, mutect2
- CDON | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.077); catalogued as COSV54997183, COSV99702182; called by muse, mutect2, varscan2
- CIT | c.5900G>T p.R1967L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV55866472; called by muse, mutect2
- COL8A2 | c.535G>C p.G179R | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57441372; called by muse, mutect2, varscan2
- CRACD | c.3301C>T p.R1101W | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1355649127, COSV51719610; called by muse, mutect2, varscan2
- CROT | c.491C>G p.S164C | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as COSV58973858, COSV58977410; called by muse, mutect2
- CUL9 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 17/294 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.057); catalogued as rs548294417, COSV52727767; called by muse, mutect2
- CWH43 | c.1816A>G p.T606A | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as COSV56938135; called by muse, mutect2, varscan2
- DLG5 | c.3373C>G p.P1125A | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV64947669; called by muse, mutect2
- DLGAP1 | c.679T>A p.C227S | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.052); catalogued as COSV59798826; called by muse, mutect2, varscan2
- DPP10 | c.2177C>A p.A726D | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59681095; called by muse, mutect2
- DPYSL2 | c.702A>T p.E234D | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV60783050; called by muse, mutect2, varscan2
- DVL3 | c.1385G>T p.R462M | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100493656; called by muse, mutect2, varscan2
- DVL3 | c.1386G>T p.R462S | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100493658; called by muse, mutect2, varscan2
- DYNLT3 | c.244A>T p.S82C | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as COSV66078856; called by muse, mutect2, varscan2
- EP400 | c.8260C>T p.Q2754* | Nonsense Mutation (SNP) | VAF 14/80 reads (18%) | catalogued as COSV57764787; called by muse, mutect2, varscan2
- EWSR1 | c.1608G>C p.W536C | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58423092, COSV58423328; called by muse, mutect2, varscan2
- EXOC4 | c.1337C>T p.S446L | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.173); catalogued as rs545066605, COSV54094083; called by muse, mutect2, varscan2
- FAM135A | c.2356G>A p.D786N (on ENST00000370479 / NM_001351599.1; = p.D573N on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); catalogued as COSV52050325; called by muse, mutect2, varscan2
- FAT3 | c.2150C>G p.S717* | Nonsense Mutation (SNP) | VAF 9/194 reads (5%) | catalogued as COSV53101384, COSV99963353; called by muse, mutect2
- FAT3 | c.5533G>T p.A1845S | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.069); catalogued as rs1188181623, COSV53101408; called by muse, mutect2, varscan2
- FDX2 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV58532844; called by muse, mutect2, varscan2
- FOXJ2 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV50818322; called by muse, mutect2
- GMDS | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.053); catalogued as COSV66414172; called by muse, mutect2, varscan2
- HMG20A | c.665C>T p.T222I | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60312214; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.763A>T p.N255Y (on ENST00000354667 / NM_031243.3; = p.N243Y on NM_002137.4) | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.352); catalogued as COSV61158764; called by muse, mutect2, varscan2
- HOXC5 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781526097, COSV54536757, COSV54537745; called by muse, mutect2, varscan2
- HS3ST1 | c.905G>C p.R302T | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV50023406; called by muse, mutect2, varscan2
- KAT6A | c.4318G>T p.E1440* | Nonsense Mutation (SNP) | VAF 79/205 reads (39%) | catalogued as COSV55905305; called by muse, mutect2, varscan2
- KCNB1 | c.1681G>C p.E561Q | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.972); catalogued as COSV65567589; called by muse, mutect2
- KCNT1 | c.3536C>A p.P1179H (on ENST00000488444; = p.P1184H on NM_020822.3) | Missense Mutation (SNP) | VAF 55/90 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53699991; called by muse, mutect2, varscan2
- KEAP1 | c.1490G>T p.W497L | Missense Mutation (SNP) | VAF 50/80 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV50276071; called by muse, mutect2, varscan2
- KIAA1614 | c.559C>A p.P187T | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.101); catalogued as COSV62552744; called by muse, mutect2, varscan2
- LAMP1 | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 19/117 reads (16%) | catalogued as COSV58149677; called by muse, mutect2, varscan2
- LRRC23 | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as COSV50387996; called by muse, varscan2
- MED26 | c.819C>A p.F273L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99659994; called by muse, mutect2, varscan2
- MGAT5B | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.341); catalogued as rs777761975, COSV56928263; called by muse, mutect2, varscan2
- MOCS3 | c.956C>T p.S319L | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.231); catalogued as rs1280787119, COSV54866130, COSV54866265; called by muse, mutect2, varscan2
- MTTP | c.1036C>A p.Q346K | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV55505354; called by muse, mutect2, varscan2
- MUC17 | c.4484C>T p.S1495F | Missense Mutation (SNP) | VAF 60/311 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV60281069, COSV60286296; called by muse, mutect2, varscan2
- NEBL | c.1516C>G p.L506V | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.563); catalogued as COSV65802544; called by muse, mutect2
- NEDD4 | c.3650A>G p.Y1217C (on ENST00000508342 / NM_001284338.1; = p.Y798C on NM_006154.4) | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1452979539, COSV59060816; called by muse, mutect2, varscan2
- NLRP1 | c.3265G>A p.E1089K | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.969); catalogued as COSV52562446; called by muse, mutect2, varscan2
- NUDCD2 | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.606); catalogued as COSV57084528; called by muse, mutect2, varscan2
- OR10G8 | c.704G>C p.R235T | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV70908213, COSV70908425; called by muse, mutect2, varscan2
- OR6B1 | c.652T>C p.Y218H | Missense Mutation (SNP) | VAF 95/213 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769317140, COSV68770025; called by muse, mutect2, varscan2
- PAFAH2 | c.1048G>A p.V350I | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as rs775261231, COSV65339424; called by muse, mutect2, varscan2
- PAX1 | c.562G>T p.D188Y | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1163739863, COSV68271582; called by muse, mutect2, varscan2
- PCDHB14 | c.1687T>C p.Y563H | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.32); catalogued as COSV99505870; called by muse, mutect2, varscan2
- PDE7A | c.92C>G p.S31C | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV67523614; called by muse, mutect2, varscan2
- PHLPP2 | c.2914C>T p.P972S | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV62424073; called by muse, mutect2, varscan2
- PKD1 | c.6145G>A p.E2049K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.247); catalogued as COSV51914480; called by muse, mutect2, varscan2
- PLPPR4 | c.1660C>G p.R554G | Missense Mutation (SNP) | VAF 15/163 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV64565487, COSV64567434; called by muse, mutect2
- POTEF | c.3181G>T p.E1061* | Nonsense Mutation (SNP) | VAF 103/217 reads (47%) | catalogued as COSV62540840; called by muse, mutect2, varscan2
- PROCA1 | c.429C>G p.F143L (on ENST00000439862 / NM_001366301.1; = p.F115L on NM_152465.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/214 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as rs1255191357, COSV56386305; called by muse, mutect2, varscan2
- R3HCC1L | c.847G>C p.D283H | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV54400624, COSV54405250; called by muse, mutect2, varscan2
- R3HCC1L | c.1091G>C p.G364A | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as COSV54400639; called by muse, mutect2, varscan2
- RALGAPB | c.3868G>A p.D1290N | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.52); catalogued as COSV53434423, COSV53436881; called by muse, mutect2, varscan2
- RARS2 | c.741G>C p.L247F | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.111); catalogued as COSV101057054, COSV65760912; called by muse, mutect2, varscan2
- RBM17 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV65913856; called by muse, mutect2
- RELN | c.8974G>A p.E2992K | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as COSV100634971, COSV58994520; called by muse, mutect2, varscan2
- RPAP1 | c.3443G>T p.W1148L | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV58538476; called by muse, mutect2, varscan2
- RPTOR | c.233C>A p.T78N | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV60807427; called by muse, mutect2, varscan2
- SETBP1 | c.4235G>A p.R1412Q | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56319614, COSV99952306; called by muse, mutect2, varscan2
- SH3GL2 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as COSV66049083; called by muse, mutect2, varscan2
- SLC4A2 | c.1319G>T p.R440L | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV59656658; called by muse, mutect2
- SLC9A5 | c.2270G>A p.C757Y | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.135); catalogued as COSV55361685; called by muse, mutect2, varscan2
- SMARCC2 | c.2464G>C p.E822Q | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.076); catalogued as COSV57217412; called by muse, mutect2
- SON | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.093); catalogued as rs201446136; called by muse, mutect2, varscan2
- SRCAP | c.8117C>A p.S2706* | Nonsense Mutation (SNP) | VAF 12/138 reads (9%) | catalogued as COSV52671282; called by muse, mutect2
- SYNJ1 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.836); catalogued as COSV59147254, COSV59151142; called by muse, mutect2, varscan2
- SYNPO2 | c.838G>T p.G280* | Nonsense Mutation (SNP) | VAF 23/50 reads (46%) | catalogued as COSV61109626; called by muse, mutect2, varscan2
- TECTA | c.2412del p.K805Sfs*19 | Frame Shift Del (DEL) | VAF 46/173 reads (27%) | catalogued as COSV50818673; called by mutect2, pindel, varscan2
- TLR4 | c.2369G>A p.S790N (on ENST00000355622 / NM_138554.5; = p.S750N on NM_003266.4) | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV62923050; called by muse, mutect2
- TNFAIP3 | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.76); catalogued as COSV52797131, COSV52798283; called by muse, mutect2
- TNR | c.2446G>A p.E816K | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.077); catalogued as COSV54875537, COSV54919367; called by muse, mutect2, varscan2
- TRIM27 | c.168C>G p.C56W | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65873479; called by muse, mutect2, varscan2
- TRO | c.2056G>A p.D686N | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs745852431, COSV51499620; called by muse, mutect2, varscan2
- TUBA3E | c.1005C>G p.I335M | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.936); catalogued as COSV56058808; called by muse, mutect2, varscan2
- UACA | c.1083A>T p.E361D | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV59855191; called by muse, mutect2, varscan2
- VPS13C | c.7483C>G p.H2495D (on ENST00000644861 / NM_020821.3; = p.H2452D on NM_017684.5) | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.021); catalogued as COSV51158168; called by muse, mutect2, varscan2
- VPS8 | c.3041G>A p.G1014D (on ENST00000625842 / NM_001349294.1; = p.G1012D on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.283); catalogued as rs748057572, COSV54983952; called by muse, mutect2
- WDR1 | c.1195A>T p.S399C (on ENST00000382452; = p.S259C on NM_005112.5) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as COSV66723918, COSV66724835; called by muse, mutect2, varscan2
- WNK1 | c.1514G>T p.R505L | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV60031268; called by muse, mutect2, varscan2
- XYLT1 | c.1547A>G p.K516R | Missense Mutation (SNP) | VAF 53/397 reads (13%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.725); catalogued as rs200026293, COSV54482565; called by muse, mutect2, varscan2
- YAE1 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56232882; called by muse, mutect2
- ZBTB40 | c.755C>G p.S252* | Nonsense Mutation (SNP) | VAF 10/87 reads (11%) | catalogued as COSV65145148; called by muse, varscan2
- ZFAND4 | c.958G>C p.D320H | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV60858428, COSV60858714; called by muse, mutect2, varscan2
- ZFP36 | c.148G>T p.D50Y (on ENST00000594442; = p.D44Y on NM_003407.5) | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs773711012, COSV50528013; called by muse, mutect2, varscan2
- ZMYM6 | c.956T>C p.V319A | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.695); catalogued as COSV64120700; called by muse, mutect2
- ZNF318 | c.3664G>C p.E1222Q | Missense Mutation (SNP) | VAF 39/303 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV58931981; called by muse, mutect2, varscan2
- ZNF319 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.71); catalogued as COSV54621081; called by muse, mutect2, varscan2
- GTF2IRD2 | c.424G>T p.A142S | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- IGLV3-22 | c.188_189insTATACTA p.E63Dfs*10 | Frame Shift Ins (INS) | VAF 14/50 reads (28%) | called by mutect2, varscan2
- LRRC23 | c.390del p.M130Ifs*31 | Frame Shift Del (DEL) | VAF 66/409 reads (16%) | called by mutect2, pindel*, varscan2
- RIF1 | c.7147dup p.T2383Nfs*8 | Frame Shift Ins (INS) | VAF 17/106 reads (16%) | called by mutect2, pindel, varscan2
- APOL5 | c.1026G>A p.R342= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as rs1327925913, COSV50766747; called by muse, mutect2, varscan2
- ARHGAP30 | c.1897C>T p.L633= | Silent (SNP) | VAF 30/313 reads (10%) | catalogued as COSV63515992; called by muse, mutect2
- ASXL3 | c.3330C>T p.L1110= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV52463642; called by muse, mutect2, varscan2
- BAZ2B | c.5442T>C p.S1814= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as COSV58599269; called by muse, mutect2, varscan2
- CASS4 | c.2307G>A p.A769= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as rs374797932; called by muse, mutect2, varscan2
- CD1B | c.189C>A p.G63= | Silent (SNP) | VAF 131/505 reads (26%) | catalogued as COSV63804157, COSV63805125; called by muse, mutect2, varscan2
- COG3 | c.417G>A p.E139= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as rs769657274, COSV63072282; called by muse, mutect2, varscan2
- DCAF4L2 | c.1071C>T p.P357= | Silent (SNP) | VAF 36/90 reads (40%) | catalogued as rs762077763, COSV60476760, COSV60478009; called by muse, mutect2, varscan2
- DNAH9 | c.1422T>C p.A474= | Silent (SNP) | VAF 45/132 reads (34%) | catalogued as COSV52345831; called by muse, mutect2, varscan2
- EFCAB5 | c.4491G>A p.G1497= | Silent (SNP) | VAF 51/146 reads (35%) | catalogued as COSV57928702; called by muse, mutect2, varscan2
- F3 | c.465G>C p.V155= | Silent (SNP) | VAF 24/43 reads (56%) | catalogued as COSV61844831, COSV61844932; called by muse, mutect2, varscan2
- FDPS | c.633C>G p.L211= | Silent (SNP) | VAF 8/159 reads (5%) | catalogued as COSV100756256, COSV63114335; called by muse, mutect2
- FLNC | c.6138C>G p.V2046= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV57954539; called by muse, mutect2, varscan2
- GUCY2C | c.2691C>T p.A897= | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as COSV53789300; called by muse, mutect2, varscan2
- HTT | c.7773C>A p.L2591= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100750761; called by muse, mutect2, varscan2
- ICE1 | c.5298C>T p.L1766= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV56821980; called by muse, mutect2, varscan2
- IGKV1-9 | c.30G>T p.L10= | Silent (SNP) | VAF 26/237 reads (11%) | called by muse, mutect2, varscan2
- INTS4 | c.39C>T p.F13= | Silent (SNP) | VAF 24/130 reads (18%) | catalogued as COSV71088089, COSV71089797; called by muse, mutect2, varscan2
- KEL | c.1350C>T p.L450= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs201720053, COSV62334481; called by muse, mutect2, varscan2
- MYOZ2 | c.441C>T p.Y147= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs1337507818, COSV61084646; called by muse, mutect2, varscan2
- NBN | c.666C>T p.F222= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs876661098, COSV55372597, COSV55372859; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OBSCN | c.6975C>T p.G2325= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as rs367606070; called by muse, mutect2, varscan2
- OR5AP2 | c.87A>T p.L29= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV57257452; called by muse, mutect2, varscan2
- PCDHB4 | c.1167G>A p.P389= | Silent (SNP) | VAF 71/113 reads (63%) | catalogued as rs782548816, COSV52021757; called by muse, mutect2, varscan2
- PHLPP2 | c.3762C>T p.L1254= | Silent (SNP) | VAF 52/129 reads (40%) | catalogued as COSV62424066; called by muse, mutect2, varscan2
- PPP2R5E | c.66C>T p.V22= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as rs1425590534, COSV61741442; called by muse, mutect2, varscan2
- PRLHR | c.390C>T p.G130= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV53303647; called by muse, mutect2, varscan2
- RIF1 | c.7350T>C p.C2450= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as COSV54615916; called by muse, mutect2, varscan2
- SLC7A10 | c.600C>A p.L200= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV53503636; called by muse, mutect2, varscan2
- SORCS3 | c.1005C>G p.R335= | Silent (SNP) | VAF 83/217 reads (38%) | catalogued as COSV63808158; called by muse, mutect2, varscan2
- TMPRSS15 | c.246C>T p.F82= | Silent (SNP) | VAF 24/45 reads (53%) | catalogued as COSV53038598; called by muse, mutect2, varscan2
- TPD52 | c.147G>A p.L49= (on ENST00000379097 / NM_001025252.3; = p.L9= on NM_005079.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/115 reads (17%) | catalogued as COSV66950293; called by muse, mutect2, varscan2
- TRIM63 | c.405C>G p.L135= | Silent (SNP) | VAF 8/87 reads (9%) | catalogued as COSV65328237; called by muse, mutect2
- TUBA3E | c.825C>T p.V275= | Silent (SNP) | VAF 34/215 reads (16%) | called by muse, mutect2
- ZBP1 | c.849C>A p.A283= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as COSV59061418; called by muse, mutect2, varscan2
- AQR | c.471+1044A>G | Intron (SNP) | VAF 7/173 reads (4%) | called by muse, mutect2
- FAM8A1 | c.*8del | 3'UTR (DEL) | VAF 33/83 reads (40%) | catalogued as rs762584146; called by mutect2, pindel, varscan2
- IQSEC3 | c.3114+125C>G | Intron (SNP) | VAF 15/65 reads (23%) | catalogued as COSV100407176; called by muse, mutect2, varscan2
- PLXNA4 | c.1371+4284C>T | Intron (SNP) | VAF 25/66 reads (38%) | catalogued as rs200588151, COSV58115691; called by muse, mutect2, varscan2
- PNKD | c.236+1129C>T | Intron (SNP) | VAF 28/344 reads (8%) | catalogued as COSV99297950; called by muse, mutect2
